Surgical pathology report (de-identified scan), TCGA case TCGA-CN-6016, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-6016-01A (Primary Tumor).

[page 1 of 8]
Pathology Report [REDACTED] **FINAL**

Report Type Pathology Report

Date of Event [REDACTED]

Sex [REDACTED]

Authored by [REDACTED]

Hosp/Group [REDACTED]

Record Status FINAL

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, NECK LEVEL 1A (LATERALITY NOT GIVEN), SELECTIVE NECK DISSECTION

FOUR LYMPH NODES, NO TUMOR PRESENT (0/4).

PART 2: LYMPH NODES, RIGHT NECK LEVEL 1B, SELECTIVE NECK DISSECTION

A. FOUR LYMPH NODES, NO TUMOR PRESENT (0/4).

B. CHRONIC SIALADENITIS WITH PERIDUCTAL FIBROSIS AND ATROPHY.

C. UNREMARKABLE PAROTID TISSUE.

PART 3: LYMPH NODES, LEFT NECK LEVEL 1B, SELECTIVE NECK DISSECTION

D. FIVE LYMPH NODES, NO TUMOR PRESENT (0/5).

E. CHRONIC SIALADENITIS WITH PERIDUCTAL FIBROSIS AND ATROPHY.

PART 4: MANDIBLE MARROW MARGIN, LEFT, EXCISION

NO TUMOR PRESENT.

PART 5: MANDIBLE MARROW MARGIN, RIGHT, EXCISION

NO TUMOR PRESENT.

PART 6: POSTERIOR TONGUE MARGIN, RIGHT, EXCISION

NO TUMOR PRESENT.

PART 7: POSTERIOR TONGUE MARGIN, LEFT, EXCISION

NO TUMOR PRESENT.

PART 8: DEEP TONGUE MARGIN, RIGHT, EXCISION

NO TUMOR PRESENT.

PART 9: DEEP TONGUE MARGIN, LEFT, EXCISION

NO TUMOR PRESENT.

PART 10: MYLOHYOID, LEFT, EXCISION

NO TUMOR PRESENT.

PART 11: FLOOR OF MOUTH, RIGHT, EXCISION

NO TUMOR PRESENT.

PART 12: FLOOR OF MOUTH, LEFT, EXCISION

INVASIVE SQUAMOUS CELL CARCINOMA.

PART 13: ANTERIOR MANDIBULAR COMPOSITE WITH HEMIGLOSSECTOMY, EXCISION

A. INVASIVE SQUAMOUS CELL CARCINOMA (4.7 CM) MODERATELY DIFFERENTIATED, KERATINIZING, WITH ANGIOLYMPHATIC (INCLUDING VENOUS) AND PERINEURAL INVASION.

B. NO BONE INVOLVEMENT.

C. EXTRINSIC TONGUE MUSCLE INVOLVEMENT PRESENT.

D. MARGINS ARE FREE OF TUMOR (see also PARTS 4-11, 15-16).

E. PATHOLOGIC STAGE: pT4a N1.

PART 14: LYMPH NODES, RIGHT NECK ZONE 2, 3, AND 4, SELECTIVE NECK DISSECTION

TWENTY-NINE LYMPH NODES, NO TUMOR PRESENT (0/29).

[page 2 of 8]
PART 15: FLOOR OF MOUTH NEW MARGIN, LEFT, EXCISION
NO TUMOR PRESENT.

PART 16: FLOOR OF MOUTH FINAL, LEFT, EXCISION
NO TUMOR PRESENT.

PART 17: LYMPH NODES, LEFT NECK ZONE 2A, 2B, 3A AND 4, SELECTIVE NECK
DISSECTION

METASTATIC SQUAMOUS CELL CARCINOMA IN ONE OUT OF THIRTY-THREE LYMPH NODES
(1/33), 1.4 CM, LEVEL 4, WITH EXTRACAPSULAR EXTENSION.

[REDACTED]

My signature is attestation that I have personally reviewed the submitted
material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in 17 parts.

Part 1 is received fresh labeled with the patient's name, initials xx, and
"level 1A neck". It consists of a 3.3 x 2.8 x 0.9 cm portion of yellow
adipose tissue containing 7 possible lymph nodes, 0.2 x 0.2 x 0.2 cm to 1.3 x
0.8 x 0.4 cm.

Section Code:

1A - four possible lymph nodes

1B - three possible lymph nodes.

Part 2 is received fresh labeled with the patient's name, initials xx, and
"right level 1B neck". It consists of a 5.7 x 4.7 x 1.5 cm portion of yellow
adipose tissue and pink-tan fibrous tissue, containing 7 possible lymph nodes,
0.3 x 0.3 x 0.3 cm - 1.3 x 0.9 x 0.3 cm and a submandibular gland, 4.7 x 2.7 x
1.7 cm. On cut section, the submandibular gland is composed of yellow, fatty,
lobulated tissue with no distinct lesions.

Section Code:

2A - three possible lymph nodes

2B - four possible lymph nodes

2C - representative section of submandibular gland.

Part 3 is received fresh labeled with the patient's name, initials xx, and
"left neck level 1B". It consists of a 5.6 x 3.7 x 3.3 cm portion of yellow
adipose tissue and pink-tan fibrous tissue containing 6 possible lymph nodes,
0.4 x 0.4 x 0.3 cm - 1.4 x 0.9 x 0.4 cm and a submandibular gland measuring
5.7 x 3.7 x 1.4 cm. On cut section, the submandibular gland is composed of
yellow, fatty, lobulated tissue with no distinct lesions.

Section Code:

3A - three possible lymph nodes

3B - three possible lymph nodes

3C - representative section of submandibular gland.

Part 4 is received fresh for intraoperative consultation labeled with the
patient's name, initials xx and "left mandible marrow margin". It consists
of two fragments of tan bony tissue with attached soft tissue, measuring 0.3 x
0.3 x 0.2 cm and 0.5 x 0.4 x 0.1 cm. The frozen soft tissue is submitted in
cassette 4AFS. The bony fragments are submitted in 4BDR.

Part 5 is received fresh for intraoperative consultation labeled with the
patient's name, initials xx and "right mandible marrow margin". It consists
of two fragments of bony tissue with attached soft tissue measuring 0.3 x 0.2

[page 3 of 8]
x 0.2 cm each. The frozen soft tissue is submitted for permanent section in cassette 5AFS and the bony tissue is submitted in cassette 5BDR.

Part 6 is received fresh labeled with the patient's name, initials xx and "right posterior tongue margin". It consists of three fragments of tan-brown soft tissue measuring 1.5 x 0.5 x 0.3 cm, 1.5 x 0.4 x 0.3 cm and 0.6 x 0.4 x 0.4 cm. The frozen tissue is submitted for permanent sections in cassette 6AFS.

Part 7 is received fresh labeled with the patient's name, initials xx and "left posterior tongue margin". It consists of a 1.3 x 0.3 x 0.3 cm portion of tan-brown soft tissue. The frozen tissue is submitted for permanent section in cassette 7AFS.

Part 8 is received for intraoperative consultation labeled with the patient's name, initials xx, and "right deep tongue margin". It consists of a 1.1 x 0.8 x 0.6 cm portion of tan-brown soft tissue. The frozen tissue is submitted for permanent section in cassette 8AFS.

Part 9 is received fresh for intraoperative consultation labeled with the patient's name, initials xx and "left deep tongue margin". It consists of a 1.2 x 0.9 x 0.5 cm portion of red-brown soft tissue. The frozen tissue is submitted for permanent section in cassette 9AFS.

Part 10 is received fresh for intraoperative consultation labeled with the patient's name, initials xx and "mylohyoid left". It consists of a 1.1 x 0.5 x 0.6 cm portion of red-brown soft tissue. The frozen tissue is submitted for permanent section in cassette 10AFS.

Part 11 is received fresh for intraoperative consultation labeled with the patient's name, initials xx and "right floor of mouth". It consists of a 0.7 x 0.4 x 0.3 cm portion of tan-red soft tissue. The frozen tissue is submitted for permanent section in cassette 11AFS.

Part 12 is received fresh for intraoperative consultation labeled with the patient's name, initials xx and "left floor of mouth". It consists of a 1.2 x 0.7 x 0.3 cm portion of tan-brown and red soft tissue. The frozen tissue is submitted for permanent section in cassette 12AFS.

Part 13 is received fresh labeled with the patient's name, initials xx and "anterior mandibular composite with hemiglossectomy". It consists of a 5.7 x 5.1 x 4.3 cm anterior hemiglossectomy with attached mandible measuring 5.9 x 2.7 x 2.2 cm. The tongue is firm and on cut section shows a white, poorly defined, unencapsulated lesion measuring 4.7 x 3.3 x 1.5 cm and extending into the extrinsic muscles of the tongue, abutting the bone, but not grossly involving bone.

Section Code:

13ADR - left bone margin

13BDR - right bone margin

13CDR - tumor with bone

13E-13H - tumor involving extrinsic muscles of the tongue

13D, 13G-13H - representative sections of tumor.

Digital photos are taken. Tissue is collected for banking.

Part 14 is received fresh labeled with the patient's name, initials xx and "right neck zone 2, 3, and 4". It consists of a 7.8 x 4.2 x 1.8 cm unoriented portion of yellow adipose tissue and tan-red fibrous tissue. The tissue is separated into three levels, levels 2, 3 and 4. Level 2 contains 8 potential lymph nodes, 0.3 x 0.2 x 0.2 cm - 1.2 x 1.0 x 0.4 cm. Level 3 contains 8 potential lymph nodes, 0.5 x 0.3 x 0.3 cm - 1.3 x 1.1 x 0.5 cm. Level 4 contains 11 potential lymph nodes, 0.2 x 0.2 x 0.2 cm - 2.3 x 1.5 x 0.3 cm.

Section Code:

14A - five potential lymph nodes from level 2

14B - three potential lymph nodes from level 2

14C - five potential lymph nodes from level 3

[page 4 of 8]
14D - three potential lymph nodes from level 3

14E - two potential lymph nodes from level 4

14F - four potential lymph nodes from level 4

14G - five potential lymph nodes from level 4.

Part 15 is received fresh for intraoperative consultation labeled with the patient's name, initials xx and "left floor of mouth new margin, inked true margin, suture anterior, medial black". It consists of a 2.5 x 0.9 x 0.7 cm portion of tan-red tissue with white mucosa. The frozen tissue is submitted for permanent section in cassette 15AFS.

Part 16 is received fresh labeled with the patient's name, initials xx and "left floor of mouth final". It consists of a 0.4 x 0.3 x 0.3 cm portion of tan-red soft tissue. It is entirely submitted in cassette 16A.

Part 17 is received fresh labeled with the patient's name, initials xx and "left neck zone 2A, 2B, 3 and 4, suture zone 4". It consists of two unoriented fragments of yellow adipose tissue and tan-red fibrous tissue, 12.5 x 4.8 x 0.8 cm with a suture at one end, and 4.6 x 3.3 x 0.8 cm. The larger fragment is divided into three levels based on orientation. Level 2 contains 10 possible lymph nodes, 0.3 x 0.2 x 0.2 cm - 1.3 x 1.1 x 0.3 cm. Level 3 contains 10 possible lymph nodes, 0.6 x 0.2 x 0.2 cm - 1.3 x 0.5 x 0.2 cm. Level 4 contains 5 possible lymph nodes, 0.2 x 0.2 x 0.2 cm - 2.2 x 1.2 x 0.9 cm, the largest of which is grossly involved by tumor and has a white firm cut surface. The second fragment of tissue contains 4 possible lymph nodes measuring 0.5 x 0.3 x 0.3 cm to 0.7 x 0.4 x 0.4 cm.

Section Code:

17A - two possible lymph nodes from level 2

17B - four possible lymph nodes from level 2

17C - four possible lymph nodes from level 2

17D - four possible lymph nodes from level 3

17E - three possible lymph nodes from level 3

17F - three possible lymph nodes from level 3

17G - one lymph node from level 4, grossly involved by tumor, bisected

17H - four possible lymph nodes from level 4

17I - four possible lymph nodes from smaller fragment.

Grossed By: [REDACTED]

INTRAOPERATIVE CONSULTATION:

4A: LEFT MANDIBLE MARROW MARGIN (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

5A: RIGHT MANDIBLE MARROW MARGIN (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

6A: RIGHT POSTERIOR TONGUE MARGIN (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

7A: LEFT POSTERIOR TONGUE MARGIN (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

8A: RIGHT DEEP TONGUE MARGIN (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

9A: LEFT DEEP TONGUE MARGIN (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

10A: MYLOHYOID LEFT (frozen section)

A. BENIGN.

[page 5 of 8]
B. NO TUMOR PRESENT ([REDACTED]).

11A: RIGHT FLOOR OF MOUTH (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

12A: LEFT FLOOR OF MOUTH (frozen section)

A. MALIGNANT.

B. MICROSCOPIC FOCUS OF SQUAMOUS CELL CARCINOMA [REDACTED] [REDACTED] .

15A: LEFT FLOOR OF MOUTH NEW MARGIN (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by the [REDACTED] h, Department of Pathology, as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of 2 to a maximum of 84 hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND TUMORS

SPECIMEN TYPE: Resection: anterior mandibular composite with hemiglossectomy

TUMOR SITE: Oral Cavity

TUMOR SIZE: Greatest dimension: 4.7 cm

Additional dimensions: 3.3 x 1.5 cm

HISTOLOGIC TYPE: Squamous cell carcinoma, conventional

HISTOLOGIC GRADE: G2

PRIMARY TUMOR (pT): pT4a

REGIONAL LYMPH NODES (pN): pN1

Number of regional lymph nodes examined: 75

Number of regional lymph nodes involved: 1

Extra-capsular extension of nodal tumor: Present

DISTANT METASTASIS (pM): pMX

MARGINS: Margins uninvolved by tumor

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

Present

PERINEURAL INVASION: Present

ADDITIONAL PATHOLOGIC FINDINGS: None identified

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Oral cavity cancer.

PROCEDURE: Composite, neck dissection.

SPECIFIC CLINICAL QUESTION: Tumor, nodes, margins.

[page 6 of 8]
OUTSIDE TISSUE DIAGNOSIS: Yes, diagnosis SCCA.
PRIOR MALIGNANCY: No.
CHEMORADIATION THERAPY: No.
ORGAN TRANSPLANT: No.
IMMUNOSUPPRESSION: No.
OTHER DISEASES: No.
CYTOGENETICS TESTS: Not answered.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Level 1A Neck

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

Part 2: Right Level 1B Neck

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

Part 3: Left Neck Level 1B

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

Part 4: Left Mandible Marrow Margin

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Decal x 1 BDR

H&E x 1 BDR

Part 5: Right Mandible Marrow Margin

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Decal x 1 BDR

H&E x 1 BDR

Part 6: Right Posterior Tongue Margin

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 7: Left Posterior Tongue Margin

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 8: Right Deep Tongue Margin

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 9: Left Deep Tongue Margin

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 10: Mylohyoid Left

Taken: [REDACTED] [REDACTED]

[page 7 of 8]
Stain/cnt Block

H&E x 1 AFS

Part 11: Right Floor of Mouth

Taken:

Stain/cnt Block

H&E x 1 AFS

Part 12: Left Floor of Mouth

Taken:

Stain/cnt Block

H&E x 1 AFS

Part 13: Anterior Mandibular Composite with Hemiglossectomy

Taken:

Stain/cnt Block

H&E x 1 D

H&E x 1 E

H&E x 1 F

DOG1 x 1 G

ANEG x 1 G

H&E Recut x 1 G

IEGFR x 1 G

IBNKNC x 1 G

IBNKNC x 1 G

IBNKNC x 1 G

IBNKNC x 1 G

IBNKNC x 1 G

IBNKNC x 1 G

H&E x 1 G

HPV x 1 G

P16 x 1 G

V-EGFR x 1 G

H&E x 1 H

Decal x 1 ADR

H&E x 1 ADR

Decal x 1 BDR

H&E x 1 BDR

Decal x 1 CDR

RHHE Lev ___ x 1 CDR

RHHE Lev ___ x 1 CDR

RHHE Lev ___ x 1 CDR

RHHE Lev ___ x 1 CDR

RHHE Lev ___ x 1 CDR

H&E x 1 CDR

Part 14: Right Neck Zone 2-4

Taken:

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

Part 15: Left Floor of Mouth New Margin

Taken:

Stain/cnt Block

H&E x 1 AFS

[page 8 of 8]
Part 16: Left Floor of Mouth Final

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

Part 17: Left Neck Zone 2A,2B,3-4 Suture Zone 4

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

DOG1 x 1 G

ANEG x 1 G

H&E x 1 G

H&E x 1 H

H&E x 1 I

TC1

Source: NCI Genomic Data Commons file ec18241f-f286-48c7-a233-79e0602a5690 (TCGA-CN-6016.76038A97-6AD5-45C9-8705-5054C5E6C4A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).